Somatic mutation profile of tumor specimen TCGA-KK-A5A1-01A (aliquot TCGA-KK-A5A1-01A-11D-A29Q-08) from TCGA case TCGA-KK-A5A1, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.3 years (26,415 days).
Specimen TCGA-KK-A5A1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a68bc62a-af6e-4738-a680-8eb2fbb38893.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A5A1-11A (Solid Tissue Normal), aliquot TCGA-KK-A5A1-11A-12D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0824991c-8ea0-4696-90fe-59bad8d32390

The open-access MAF lists 100 somatic variants for this specimen: 79 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 61, Silent 21, Nonsense Mutation 6, Frame Shift Del 5, Frame Shift Ins 4, Splice Site 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.16693G>T p.D5565Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV60932610; called by muse, mutect2
- AL441992.2 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 17/326 reads (5%) | catalogued as COSV104405677, COSV56917062; called by muse, mutect2
- ALPK2 | c.5192T>A p.I1731N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64497768; called by muse, mutect2, varscan2
- ANO4 | c.2303-1G>A p.X768_splice (on ENST00000392977 / NM_001286615.2; = p.X733_splice on NM_178826.4) | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as COSV54615559; called by muse, mutect2, varscan2
- ARHGAP10 | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.939); catalogued as COSV60607585; called by muse, mutect2, varscan2
- ASPH | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749737562, COSV65248152; called by muse, mutect2, varscan2
- BRINP3 | c.997A>T p.N333Y | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV66542939; called by muse, mutect2, varscan2
- CACNG7 | c.264A>C p.E88D | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.386); catalogued as COSV55817623; called by muse, mutect2, varscan2
- CAMK4 | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56672058; called by muse, mutect2
- CCDC102A | c.1391A>G p.K464R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV50779983; called by muse, varscan2
- CDK12 | c.1046+1G>A p.X349_splice | Splice Site (SNP) | VAF 19/62 reads (31%) | catalogued as COSV71003105; called by muse, mutect2, varscan2
- CEP76 | c.1939G>T p.V647F | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50871002; called by muse, mutect2, varscan2
- CNTN6 | c.943dup p.Y315Lfs*19 | Frame Shift Ins (INS) | VAF 31/114 reads (27%) | catalogued as rs1216775937; called by mutect2, pindel, varscan2
- CNTROB | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 26/142 reads (18%) | catalogued as COSV66609585; called by muse, mutect2, varscan2
- COL1A1 | c.4247C>T p.T1416M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as CD116612, COSV56802625; called by muse, mutect2, varscan2
- COL5A3 | c.4078C>T p.R1360* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99318423; called by mutect2, varscan2
- CPXM1 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372944936; called by muse, mutect2, varscan2
- CSN2 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV61992820; called by muse, mutect2
- DCAF13 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV52574851; called by muse, mutect2, varscan2
- DENND2A | c.1619A>C p.K540T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV52060143; called by muse, mutect2, varscan2
- DIAPH3 | c.2672A>C p.E891A (on ENST00000400324 / NM_001042517.2; = p.E628A on NM_030932.3) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57382245; called by muse, mutect2
- DVL2 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs1185832424, COSV50039980, COSV99138283; called by muse, mutect2
- EMX1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.421); catalogued as COSV50690400; called by muse, mutect2
- FAM181A | c.947A>G p.H316R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.571); catalogued as COSV50892032; called by muse, mutect2, varscan2
- FAM83C | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs760221525, COSV65583709; called by muse, mutect2, varscan2
- GJA8 | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53790869; called by muse, mutect2
- GOLIM4 | c.1341G>C p.Q447H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV58332327; called by muse, mutect2, varscan2
- GPR156 | c.233+1G>A p.X78_splice | Splice Site (SNP) | VAF 59/144 reads (41%) | catalogued as COSV59942745; called by muse, mutect2, varscan2
- GPR83 | c.805T>A p.C269S | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs776113991, COSV54721044; called by muse, mutect2, varscan2
- GRIA2 | c.1801T>A p.S601T | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV52408190, COSV99644042; called by muse, mutect2, varscan2
- HOXB8 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs1480191622, COSV53311684; called by muse, mutect2, varscan2
- IFNA13 | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200302506, COSV101489530; called by muse, mutect2, varscan2
- IGLV7-46 | c.229T>C p.S77P | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.109); catalogued as rs1156464360; called by muse, mutect2, varscan2
- IL27RA | c.313G>C p.V105L | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV54603478; called by muse, mutect2, varscan2
- KLKB1 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV52995712; called by muse, mutect2, varscan2
- KMO | c.155G>T p.R52I | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63809159; called by muse, mutect2, varscan2
- LCE1A | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58728099; called by muse, mutect2, varscan2
- LHX2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65319063; called by muse, mutect2
- LRRC28 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.879); catalogued as rs779265896, COSV57342744; called by muse, mutect2, varscan2
- MDGA2 | c.1903G>C p.A635P (on ENST00000399232 / NM_001113498.2; = p.A337P on NM_182830.4) | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV100637145, COSV62117611; called by muse, mutect2, varscan2
- MMP19 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV59453546; called by muse, mutect2, varscan2
- MYH13 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52839547, COSV52844665; called by muse, mutect2
- NCOA6 | c.2324A>G p.N775S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62868479; called by muse, mutect2, varscan2
- NPPA | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as COSV56742160; called by muse, mutect2
- OR10Z1 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV63524042; called by muse, mutect2, varscan2
- OR52E4 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as rs1488337976, COSV57626512; called by muse, mutect2
- P4HA1 | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201139791; called by muse, mutect2, varscan2
- PANK3 | c.135A>T p.L45F | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV53325654; called by muse, mutect2
- PPARGC1A | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.904); catalogued as COSV53534172; called by muse, mutect2, varscan2
- PPIP5K2 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as rs369390587; called by muse, mutect2, varscan2
- PRAMEF1 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV60019732; called by muse, mutect2
- PSD | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs766746185, COSV50065471; called by muse, mutect2
- RASGEF1C | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.148); catalogued as rs373050178; called by muse, mutect2
- RIMBP2 | c.1802C>A p.P601Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV55485622; called by muse, mutect2
- RNF31 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV53761517; called by muse, mutect2, varscan2
- SEC16B | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57630556; called by muse, mutect2, varscan2
- SHISAL1 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV66988956; called by muse, mutect2, varscan2
- SLC10A2 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV55362030; called by muse, mutect2, varscan2
- SON | c.1155del p.P386Hfs*14 | Frame Shift Del (DEL) | VAF 21/123 reads (17%) | catalogued as COSV99279581; called by mutect2, pindel, varscan2
- SYNJ1 | c.2188G>T p.A730S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59157595; called by mutect2, varscan2
- SYVN1 | c.1468C>G p.R490G (on ENST00000377190 / NM_172230.3; = p.R489G on NM_032431.3) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV53697631; called by muse, mutect2, varscan2
- TERF2IP | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV55614437; called by muse, varscan2
- TNIK | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs769775980, COSV52675745, COSV52697973; called by muse, mutect2, varscan2
- TUB | c.1022T>C p.F341S (on ENST00000299506 / NM_177972.3; = p.F396S on NM_003320.4) | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55110347; called by muse, mutect2, varscan2
- VAMP7 | c.73T>C p.F25L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV52903229; called by muse, mutect2, varscan2
- VDAC1 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.567); catalogued as rs767734111, COSV54738670; called by muse, mutect2, varscan2
- XPNPEP3 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV64028568; called by muse, mutect2, varscan2
- ZBTB22 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56473231; called by muse, mutect2, varscan2
- ZNF225 | c.1517A>G p.H506R | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53473472; called by muse, mutect2, varscan2
- ZNF587 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 34/128 reads (27%) | catalogued as COSV57151093; called by muse, varscan2
- ADAM29 | c.2117dup p.Q707Afs*21 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- CDK12 | c.1763_1776del p.T588Ifs*48 | Frame Shift Del (DEL) | VAF 101/250 reads (40%) | called by mutect2, pindel, varscan2
- FAM43B | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- GPAM | c.1586_1587del p.S529* | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel*, varscan2*
- ITPR1 | c.5700del p.A1901Lfs*8 (on ENST00000354582; = p.A1846Lfs*8 on NM_002222.7) | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- PRAMEF7 | c.1261C>A p.Q421K | Missense Mutation (SNP) | VAF 26/329 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- SOX9 | c.779dup p.E261Rfs*35 | Frame Shift Ins (INS) | VAF 29/176 reads (16%) | called by mutect2, pindel, varscan2
- TSTD2 | c.140dup p.K48Efs*26 | Frame Shift Ins (INS) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- ZDHHC24 | c.649del p.H217Mfs*82 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel
- AHNAK2 | c.12315C>A p.A4105= | Silent (SNP) | VAF 151/391 reads (39%) | catalogued as COSV60932626; called by muse, mutect2, varscan2
- AHNAK2 | c.3138C>T p.L1046= | Silent (SNP) | VAF 37/217 reads (17%) | catalogued as rs780324401, COSV60932640; called by muse, mutect2, varscan2
- APOB | c.11361C>T p.P3787= | Silent (SNP) | VAF 98/205 reads (48%) | catalogued as rs200979977, COSV51951491; called by muse, mutect2, varscan2
- CAMK1G | c.1329C>A p.A443= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV50527476; called by muse, mutect2
- CBLN2 | c.225C>T p.D75= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV54052958; called by muse, mutect2, varscan2
- CEP120 | c.2511A>G p.A837= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV60268986; called by muse, mutect2, varscan2
- CRLF1 | c.414C>T p.P138= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs199728865, COSV66505738; called by muse, mutect2, varscan2
- F13B | c.228T>C p.C76= | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as COSV66375909; called by muse, mutect2, varscan2
- LY9 | c.813C>G p.L271= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV54438420; called by muse, mutect2, varscan2
- MAP1S | c.411T>G p.P137= | Silent (SNP) | VAF 6/140 reads (4%) | catalogued as COSV60724860; called by muse, mutect2
- PRF1 | c.756C>T p.N252= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs150053969; called by muse, mutect2, varscan2
- PXDNL | c.1371G>T p.G457= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as rs1251828564, COSV62499868; called by muse, mutect2
- PXYLP1 | c.702C>T p.H234= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as rs1370670868, COSV53893729; called by muse, mutect2
- RALYL | c.723G>T p.L241= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV72826169; called by muse, mutect2, varscan2
- RMC1 | c.1581C>T p.L527= | Silent (SNP) | VAF 38/287 reads (13%) | catalogued as COSV52575062; called by muse, mutect2, varscan2
- SLC4A1 | c.1797C>A p.G599= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV52263552; called by muse, mutect2, varscan2
- STARD13 | c.1986C>T p.G662= (on ENST00000336934 / NM_001243476.3; = p.G544= on NM_052851.3) | Silent (SNP) | VAF 27/197 reads (14%) | catalogued as rs1000935855, COSV55237383; called by muse, mutect2, varscan2
- TDRKH | c.1122G>A p.R374= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV58619924; called by muse, mutect2
- VPS18 | c.1224C>T p.F408= | Silent (SNP) | VAF 7/123 reads (6%) | catalogued as COSV55028848; called by muse, mutect2
- ZMYM4 | c.4429C>T p.L1477= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV58907031; called by muse, mutect2
- ZNF781 | c.567C>T p.L189= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV62203061; called by muse, mutect2, varscan2
